TARGET case TARGET-10-PANFNZ — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c586895-4b91-5041-b734-63183f7a7c5d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,778 days (7.6 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.0 years (1,470 days); Year of diagnosis: 2004; Days to last follow up: 2,778 days (7.6 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 2,357 days (6.5 years); Days to first event: 2,357 days (6.5 years); First event: Relapse.
- Days to follow up: 2,778 days (7.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 144 ×10³/µL.
- Day 8: Bone Marrow blast count 88%.
- Day 15: Bone Marrow blast count 33%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 1.02%.
- Day 43: Bone Marrow blast count 0%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (4 samples)
- Sample TARGET-10-PANFNZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PANFNZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PANFNZ-14A, TARGET-10-PANFNZ-14B (2 with the same recorded description): Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 2778
- WBC at Diagnosis: 143.7
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 1.02
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 88
- BMA Blasts Day 15: 33
- BMA Blasts Day 29: 1
- BMA Blasts Day 43: 0
- Karyotype: 46,XX[20]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
